Gene-level copy-number profile of tumor specimen TCGA-DX-A8BZ-01A from TCGA case TCGA-DX-A8BZ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 79.0 years (28,853 days).
Specimen TCGA-DX-A8BZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.026035e0-8d0d-489d-993a-470999d6a522.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/009fc586-6a2a-4b13-999b-81486d35b8b6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 14,779; copy number 2: 42,255; copy number 3: 2,603; copy number 4: 109; copy number 7: 22; copy number 8: 7; copy number 10: 16; copy number 11: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BZ-01A-11D-A37B-01): tumor purity 0.74, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,929,457–22,455,740, 11 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 39 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:82,609,652–82,866,508, 7 genes, copy number 8: RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3.
- chr18:40,245,879–40,247,367, 1 gene, copy number 7: AC068688.1.
- chr18:61,905,255–62,187,118, 1 gene, copy number 7 (within-gene range 2–7): PIGN.
- chr18:62,187,255–63,726,432, 30 genes, copy number 7–10: RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3.

Autosomal genes at a single copy (total copy number 1): 13,590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
